Somatic mutation profile of tumor specimen 0DN9EQ from CCDI case PBCBLT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.9 years (1,422 days).
Specimen 0DN9EQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9aa4cd22-9388-403e-8df1-d1742b906381.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN9EY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26b94ed5-28cb-4e8a-be04-ed1540972073

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ITGB8 | c.1112C>A p.A371E | Missense Mutation (SNP) | VAF 362/1331 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.24); catalogued as rs200150010; called by muse, mutect2, varscan2
- KRT73 | c.726C>T p.D242= | Splice Region (SNP) | VAF 29/526 reads (6%) | catalogued as rs115179423, COSV59841882; called by muse, mutect2
- OPRK1 | c.311C>A p.A104E | Missense Mutation (SNP) | VAF 34/1200 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55570663; called by muse, mutect2
- SCN4A | c.2113C>G p.L705V | Missense Mutation (SNP) | VAF 42/442 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.759); catalogued as rs973100001; called by muse, mutect2
- TCN1 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 410/1113 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs77116206, COSV57253579; called by muse, mutect2, varscan2
- PERM1 | c.1424T>C p.V475A | Missense Mutation (SNP) | VAF 118/293 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PHF8 | c.206G>A p.S69N (on ENST00000357988 / NM_001184896.1; = p.S33N on NM_015107.3) | Missense Mutation (SNP) | VAF 22/356 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2
- OR9I1 | c.795C>A p.G265= | Silent (SNP) | VAF 28/1058 reads (3%) | catalogued as rs1474584062; called by muse, mutect2
- OTOGL | c.3820T>C p.L1274= (on ENST00000547103; = p.L1265= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 380/868 reads (44%) | called by muse, varscan2
- SORCS1 | c.1044C>T p.C348= | Silent (SNP) | VAF 333/900 reads (37%) | called by muse, mutect2, varscan2
- TACC3 | c.750G>A p.S250= | Silent (SNP) | VAF 250/576 reads (43%) | catalogued as rs768160358; called by muse, mutect2, varscan2
- C7orf25 | c.-85C>G | 5'UTR (SNP) | VAF 76/493 reads (15%) | called by muse, mutect2, varscan2
